Surgical pathology report (de-identified scan), TCGA case TCGA-06-A6S0, project TCGA-GBM (Glioblastoma Multiforme), tissue source site Henry Ford Hospital, specimen TCGA-06-A6S0-01A (Primary Tumor).

[page 1 of 3]
C6CF ICD-O-3
Glioblastoma, multiforme
9446/3
path
Glioblastoma NOS
9440/3
C6CF
Site Brain NOS
C71.9
path
@ Brain, supratentorial
C71.0
JW 7/24/13

Surgical Pathology Report

Patient Name: Phone #: Accession #:
Med. Rec. #: Client: Taken:
DOB: (Age:) Location: Received:
Gender: M Accnt: Reported:
Physician(s):
Phy Location:

Clinical History

A 67-year-old man experienced left sided numbness and weakness, and on imaging there was a left frontal lobe lesion with hemorrhage and some peripheral enhancement. The lesion has progressively enlarged to 5.4 cm, has satellite lesions, and has FLAIR signal extending into cerebral peduncle and ventral midbrain.

Operative Diagnoses

Brain tumor

Operation / Specimen

A: Brain tumor, biopsy

Pathologic Diagnosis

A and B. Brain, right, biopsy: Glioblastoma.

See Microscopy Description and Comment.

Comment

The sections contain small fragments of an astrocytic neoplastic proliferation that has nuclear anaplasia, mitotic activity, microvascular cellular proliferation with necrosis and thrombosis, and focal tumor necrosis. The morphological features are those of a glioblastoma.

Electronically Signed Out

Senior Staff Pathologist
Senior Staff

Consultant:
Pathologist

Procedures/Addenda

PCR for EGFR variant III mutation

Date Ordered: Date Reported:

Interpretation

NEGATIVE - No evidence of EGFRvIII mutation is detected

Surgical Pathology

Page 2 of 3

Results-Comments

TEST DESCRIPTION: Testing performed on RNA extracted from paraffin tissue block (A1)

H and E slide was examined and no microdissection was needed.

The epidermal growth factor receptor (EGFR) is an attractive molecular target in glioblastoma because it is amplified, overexpressed, and/or mutated in up to 40% to 50% of patients. Epidermal growth factor receptor variant III

(EGFRvIII) is an oncogenic, constitutively active mutant form of EGFR that is commonly expressed in glioblastoma.

Cell culture and in vivo models of glioblastoma have demonstrated EGFRvIII as defining prognostically distinct

subgroups of glioblastomas. Additionally, the presence of EGFRvIII has been shown to sensitize tumors to EGFR

[page 2 of 3]
tyrosine kinase inhibitors when the tumor suppressor protein PTEN is intact. RNA is extracted from formalin fixed, paraffin embedded tissue samples and reverse transcribed to cDNA. The cDNA is then amplified using standard PCR technique for DNA templates. PCR products are detected by gel electrophoresis. The limit of detection of this assay has been determined to be approximately 5 mutant cells in 100 normal cells.
FDA Comment: The above data are not to be construed as the results from a stand alone diagnostic test. This test was developed and its performance characteristics determined by the as required by CLIA '88 regulations. It has not been cleared or approved for specific uses by the U.S. Food and Drug Administration (FDA). The FDA has determined that such clearance or approval is not necessary. These results are provided for informational purposes only, and should be interpreted only in the context of established procedures and/or diagnostic criteria.

Electronically Signed Out

Senior Staff Pathologist

MGMT Promoter Methylation

Date Ordered: **Date Reported:**

Interpretation

NEGATIVE: No evidence of methylated MGMT promoter is detected.

Results-Comments

Testing performed on DNA extracted from tumor paraffin block (A1)
H and E slide was examined and no microdissection was needed.

TEST DESCRIPTION: Patients with glioma containing a methylated MGMT promoter have been shown to benefit

from therapy with alkylating agents. Assessment of MGMT promoter methylation status involves bisulfite treatment of

DNA followed by real-time PCR amplification of methylated and unmethylated DNA sequences. The

analytic sensitivity of this assay was determined by serial dilution of methylated positive control DNA into unmethylated DNA, and was assessed to be 1% of methylated DNA in the background of unmethylated DNA. Factors

such as the presence of >50% non-neoplastic cells in the sample, or extensive tissue necrosis, may preclude the

detection of methylated MGMT promoter sequences.

FDA COMMENT: The above data are not to be construed as the results from a stand alone diagnostic test. This test

was developed and its performance characteristics determined by the as required

by CLIA '88 regulations. It has not been cleared or approved for specific uses by the U.S. Food and Drug Administration (FDA). The FDA has determined that such clearance or approval is not necessary. These results are

provided for informational purposes only, and should be interpreted only in the context of established procedures

and/or diagnostic criteria.

Surgical Pathology

Page 3 of 3

Electronically Signed Out

Senior Staff Pathologist

Intra-Operative Consultation

A.

Brain tumor, biopsy: Gliofibrillary neoplasm, probably astrocytic, with abnormal vessels (high histological grade);

[page 3 of 3]
other. Touch preparation smears performed at and results reported to the
Physician of
Record.

Senior

Staff Pathologist
Gross Description

A.

"Brain tumor," received fresh, three fragments, 0.7 cm across. Soft, greyish-pink. In total, A1.

Microscopic Description

IMMUNOHISTOCHEMISTRY: The GFAP demonstrates prominent gliofibrillogenesis by the neoplastic cells. About 50% of the neoplastic cells over express the p53 protein. The CD34 depicts a few vascular tufts of microvascular cellular proliferation. With the MIB-1 there is a proliferation index of about 14% in the more active areas.

ICD-9(s): 239.6 239.6

Billing Fee Code(s): A:

EGFRvIII:

MGMT:

Histo Data

Part A: Brain tumor, biopsy

Taken: Received:

Stain/cnt Block Ordered Comment

CD34-DA x 1 1

EGFR vIII-curis x 1 1

mGFAP-DA x 1 1

H&E x 1 1

MGMT-curis x 1 1

MIB1-DA x 1 1

P53DO7 x 1 1

TPS H&E x 1 1

IHPAA Discrepancy		

Source: NCI Genomic Data Commons file d7ca209a-1d81-49b4-a7bb-764815fae8b5 (TCGA-06-A6S0.E69F47F2-D127-46D7-BE0A-109BE0EF97E7.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).